Somatic mutation profile of tumor specimen TCGA-13-0757-01A (aliquot TCGA-13-0757-01A-01D-0356-01) from TCGA case TCGA-13-0757, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.2 years (25,999 days).
Specimen TCGA-13-0757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aba16b9-26b6-4d89-9c20-0ce770c500f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0757-10A (Blood Derived Normal), aliquot TCGA-13-0757-10A-01D-0356-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d030157-4c33-47f6-acbe-3f149f901576

The open-access MAF lists 100 somatic variants for this specimen: 76 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 19, Intron 4, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 3, 3'UTR 1, Splice Region 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 43/51 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2027T>C p.V676A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100741701; called by muse, mutect2, varscan2
- ABO | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101505984; called by muse, mutect2, varscan2
- AC093827.5 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99892951; called by muse, mutect2, varscan2
- ACAD11 | c.250-1G>T p.X84_splice | Splice Site (SNP) | VAF 11/323 reads (3%) | catalogued as COSV99392267; called by muse, mutect2
- ARHGEF7 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99521816; called by muse, mutect2
- ASIC1 | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1166459044, COSV99948143; called by muse, mutect2, varscan2
- BMPER | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51826864; called by muse, mutect2, varscan2
- BPIFB3 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.812); catalogued as COSV100972382; called by muse, mutect2
- C10orf71 | c.1542C>A p.Y514* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100110363; called by muse, varscan2
- C1orf109 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 273/378 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs142278049; called by muse, mutect2, varscan2
- CCT4 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101075276; called by muse, mutect2, varscan2
- CD8B | c.715T>C p.W239R (on ENST00000331469 / NM_172213.4; = p.W209R on NM_172102.4) | Missense Mutation (SNP) | VAF 369/1298 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1186144128, COSV100514609; called by muse, mutect2, varscan2
- CDH10 | c.1784T>G p.M595R | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100052169; called by muse, mutect2, varscan2
- CDK5RAP1 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59428420; called by muse, mutect2, varscan2
- CDYL2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1384771327, COSV73653912; called by muse, mutect2, varscan2
- CENPF | c.4728G>A p.M1576I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1457292502, COSV100871787; called by muse, mutect2, varscan2
- CEP170 | c.3653C>T p.T1218I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV100317396; called by muse, mutect2, varscan2
- DNAH17 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV67760341; called by muse, mutect2, varscan2
- DNAH7 | c.5596C>T p.R1866* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as rs762961022, COSV100414182, COSV56785723; called by muse, mutect2, varscan2
- DNER | c.1592G>A p.C531Y | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59173951; called by muse, mutect2, varscan2
- ELFN2 | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101297584, COSV68744183; called by muse, mutect2, varscan2
- ENTPD7 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs767106170, COSV65112187; called by muse, mutect2
- EXOC6 | c.2165G>T p.R722I | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99592169; called by muse, mutect2, varscan2
- FBXL20 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52900969; called by muse, mutect2, varscan2
- FRMPD2 | c.376-1G>T p.X126_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100563971; called by muse, mutect2, varscan2
- GBA2 | c.1838A>G p.D613G | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100803433; called by muse, mutect2, varscan2
- GLI1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs913592640, COSV57357429; called by muse, mutect2, varscan2
- GPAT3 | c.997-2A>T p.X333_splice | Splice Site (SNP) | VAF 47/137 reads (34%) | catalogued as COSV100023119; called by muse, mutect2, varscan2
- GRIP2 | c.416A>T p.E139V (on ENST00000619221; = p.E42V on NM_001080423.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99817489; called by muse, mutect2, varscan2
- HPSE2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs766726702, COSV65198880; called by muse, mutect2, varscan2
- HYAL3 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs782028981, COSV100269643; called by muse, mutect2, varscan2
- IRS4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100929385; called by muse, mutect2, varscan2
- ITGBL1 | c.553T>G p.C185G | Missense Mutation (SNP) | VAF 27/826 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101095545; called by muse, mutect2
- KIRREL2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1416027236, COSV52878595, COSV52880273; called by muse, mutect2, varscan2
- KLHL40 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs764077398, COSV99825630; called by muse, mutect2, varscan2
- L3MBTL3 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs759586015, COSV100696281; called by muse, mutect2, varscan2
- LAMA1 | c.1902C>A p.Y634* | Nonsense Mutation (SNP) | VAF 28/219 reads (13%) | catalogued as COSV101056933; called by muse, mutect2, varscan2
- LRP1B | c.11814T>G p.S3938R | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.543); catalogued as COSV101257998; called by muse, mutect2, varscan2
- LYST | c.9647G>A p.R3216H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs911153079, COSV67713333; called by muse, mutect2, varscan2
- MKRN1 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99751767; called by muse, mutect2, varscan2
- MOV10 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369273991; called by muse, mutect2, varscan2
- MRTFB | c.2623C>T p.P875S (on ENST00000571589 / NM_001365412.2; = p.P825S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV100371525; called by muse, mutect2, varscan2
- MYH2 | c.3562A>G p.T1188A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV99820487; called by muse, mutect2, varscan2
- NAV3 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 95/162 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs754653329, COSV99893040; called by muse, mutect2, varscan2
- NETO1 | c.1025G>T p.S342I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.418); catalogued as COSV100199127; called by muse, mutect2, varscan2
- NIM1K | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100390261; called by muse, mutect2, varscan2
- OR2T3 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100613296; called by muse, mutect2, varscan2
- PC | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375528540; called by muse, mutect2, varscan2
- PEX19 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 163/639 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs372197333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLP1 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100393482; called by muse, mutect2, varscan2
- PPWD1 | c.1350G>C p.M450I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99731457; called by muse, mutect2, varscan2
- PRUNE2 | c.2273C>G p.T758R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100944803; called by muse, mutect2, varscan2
- PSTK | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765556280, COSV64398877; called by muse, mutect2
- RNF133 | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100411663; called by muse, mutect2, varscan2
- RREB1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100619524; called by muse, mutect2
- SMAD4 | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100748026; called by muse, mutect2
- SPAG7 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99236675; called by muse, mutect2, varscan2
- SUDS3 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV101288569; called by muse, mutect2, varscan2
- TENM1 | c.3011G>C p.G1004A | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV100950390, COSV64428640; called by muse, mutect2, varscan2
- TRMT9B | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV101501621; called by muse, mutect2
- TRPA1 | c.267A>G p.E89= | Splice Region (SNP) | VAF 11/126 reads (9%) | catalogued as COSV100084614; called by muse, mutect2
- TTN | c.4006A>G p.R1336G (on ENST00000591111; = p.R1290G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen possibly damaging (0.599); catalogued as COSV100620149; called by muse, mutect2, varscan2
- TTN | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | PolyPhen benign (0.027); catalogued as COSV100620151; called by muse, mutect2, varscan2
- UGT3A1 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 78/701 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV99954992; called by muse, mutect2, varscan2
- UNC5D | c.2563T>C p.Y855H | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54800515; called by muse, mutect2, varscan2
- XPO4 | c.1173+2T>G p.X391_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99688859; called by muse, mutect2, varscan2
- ZFP3 | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.981); catalogued as COSV100603830; called by muse, mutect2, varscan2
- ZNF420 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1187798102, COSV100421417; called by muse, mutect2, varscan2
- ZNF639 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58382831; called by muse, mutect2, varscan2
- AHNAK | c.2682_2692del p.P895Cfs*7 | Frame Shift Del (DEL) | VAF 36/293 reads (12%) | called by mutect2, pindel, varscan2
- CHAF1A | c.623_628dup p.P208_E209dup | In Frame Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- DTX3L | c.1474_1475del p.L492Dfs*33 | Frame Shift Del (DEL) | VAF 45/328 reads (14%) | called by mutect2, pindel, varscan2
- GPR179 | c.5542C>G p.L1848V (on ENST00000621958; = p.L1847V on NM_001004334.4) | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IGHG2 | c.17del p.P6Hfs*32 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, varscan2
- LRP5 | c.1833dup p.C612Vfs*25 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- ACSM2A | c.549G>T p.V183= (on ENST00000219054; = p.V104= on NM_001308169.2) | Silent (SNP) | VAF 181/820 reads (22%) | catalogued as rs780778207, COSV99525429; called by muse, mutect2, varscan2
- CDH19 | c.390T>C p.P130= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs1213783268, COSV100051852; called by muse, mutect2, varscan2
- CIT | c.1767G>T p.L589= | Silent (SNP) | VAF 93/384 reads (24%) | catalogued as COSV99950212; called by muse, mutect2, varscan2
- DSG4 | c.2265C>T p.A755= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV57397053; called by muse, mutect2, varscan2
- FCGR2B | c.213C>T p.C71= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as COSV52682984; called by muse, mutect2, varscan2
- FLYWCH1 | c.96C>T p.A32= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99559033; called by mutect2, varscan2
- GUCY2D | c.960C>T p.S320= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1284319652, COSV99644095; called by muse, mutect2, varscan2
- LINGO2 | c.237A>G p.S79= | Silent (SNP) | VAF 84/418 reads (20%) | catalogued as rs764467824, COSV100430825; called by muse, mutect2, varscan2
- MED1 | c.1962C>T p.A654= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100327958, COSV56126127; called by muse, mutect2, varscan2
- MRTFB | c.2511A>G p.Q837= (on ENST00000571589 / NM_001365412.2; = p.Q787= on NM_014048.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV100371524; called by muse, mutect2, varscan2
- MUC17 | c.2067A>T p.P689= | Silent (SNP) | VAF 131/745 reads (18%) | catalogued as rs1390801884, COSV100074122; called by muse, varscan2
- OR4C13 | c.888T>C p.I296= | Silent (SNP) | VAF 48/75 reads (64%) | catalogued as COSV101634154; called by muse, mutect2, varscan2
- PRDX5 | c.42C>T p.G14= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV99134698; called by muse, mutect2, varscan2
- RIMS2 | c.3132G>A p.E1044= (on ENST00000666250 / NM_001348490.2; = p.E852= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99176037; called by muse, mutect2, varscan2
- SFTPC | c.429C>T p.N143= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100109828; called by muse, mutect2, varscan2
- SZT2 | c.8970C>A p.G2990= (on ENST00000634258 / NM_001365999.1; = p.G2933= on NM_015284.4) | Silent (SNP) | VAF 28/484 reads (6%) | catalogued as rs1344759218, COSV100981307; called by muse, mutect2
- TAB1 | c.1317G>T p.P439= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53372574, COSV99336175; called by muse, mutect2, varscan2
- TSFM | c.981G>A p.S327= (on ENST00000323833 / NM_001172696.2; = p.S306= on NM_005726.6) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs149429981; called by muse, mutect2, varscan2
- VPS13C | c.2067T>C p.D689= (on ENST00000644861 / NM_020821.3; = p.D646= on NM_017684.5) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs561931815, COSV99829224; called by muse, mutect2, varscan2
- ACP1 | c.231+78G>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs775443798, COSV99681703; called by mutect2, varscan2
- PLXNA4 | c.1371+4415C>A | Intron (SNP) | VAF 27/706 reads (4%) | catalogued as COSV100325466; called by muse, mutect2
- SPAG11B | c.*28G>T | 3'UTR (SNP) | VAF 98/149 reads (66%) | catalogued as COSV52501156, COSV99873129; called by muse, mutect2, varscan2
- SYNPO2L | c.773-2038T>C | Intron (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100866405; called by muse, mutect2, varscan2
- TMEM179 | c.522+48C>T | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
